Somatic mutation profile of tumor specimen TCGA-AN-A0AM-01A (aliquot TCGA-AN-A0AM-01A-11W-A050-09) from TCGA case TCGA-AN-A0AM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.7 years (20,713 days).
Specimen TCGA-AN-A0AM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3058e3b9-6880-43fa-a013-769c8097a607.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0AM-10A (Blood Derived Normal), aliquot TCGA-AN-A0AM-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/300e2d39-826d-449c-b1c9-b0fb43478deb

The open-access MAF lists 85 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Nonsense Mutation 3, Splice Site 3, Splice Region 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1767G>T p.W589C | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56994288; called by muse, mutect2, varscan2
- APPBP2 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV99319397; called by muse, mutect2
- CARD8 | c.337G>C p.G113R (on ENST00000651546 / NM_001184900.3; = p.G63R on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100750976; called by muse, mutect2
- CASP7 | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100614757; called by muse, mutect2
- CATSPERB | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV56428511; called by muse, mutect2, varscan2
- CBL | c.198G>T p.V66= | Splice Region (SNP) | VAF 13/79 reads (16%) | catalogued as COSV50642064; called by muse, mutect2
- CCDC148 | c.995T>G p.F332C | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99319582; called by muse, mutect2
- CCNYL1 | c.320A>C p.H107P (on ENST00000295414 / NM_001330218.2; = p.H37P on NM_152523.2) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV99775670; called by muse, mutect2
- CTPS2 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 55/437 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63723005; called by muse, mutect2, varscan2
- CYP2A6 | c.1091A>C p.D364A | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56535820; called by muse, mutect2, varscan2
- CYP4F12 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 152/577 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761587768, COSV61172104; called by muse, mutect2, varscan2
- CYP4F12 | c.1383C>G p.F461L | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV61173514; called by muse, mutect2, varscan2
- CYP4F12 | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61174478; called by muse, varscan2
- DRP2 | c.623C>G p.A208G | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100871764, COSV65810329; called by muse, mutect2
- DSCAML1 | c.2468G>T p.G823V (on ENST00000321322; = p.G763V on NM_020693.4) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV58394502; called by muse, mutect2, varscan2
- EPHB1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as rs556035012, COSV67663308, COSV67663778; called by muse, mutect2, varscan2
- FAM20A | c.1449A>C p.E483D | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56837115; called by muse, mutect2, varscan2
- FANCD2OS | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs753651775, COSV101090871; called by muse, mutect2
- FBXL18 | c.1742C>A p.S581* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV66107699; called by muse, mutect2
- FSD2 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV100574985; called by muse, mutect2, varscan2
- GATA3 | c.994dup p.A332Gfs*20 | Frame Shift Ins (INS) | VAF 29/127 reads (23%) | catalogued as COSV60519840; called by mutect2, pindel, varscan2
- IGF1R | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 897/1472 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51303970; called by muse, mutect2, varscan2
- JTB | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99665575; called by muse, mutect2
- KIF2B | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV52132073; called by muse, mutect2, varscan2
- L3MBTL4 | c.108C>G p.S36R | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99527073; called by muse, mutect2
- MEGF10 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99174676; called by muse, mutect2
- MUC17 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV60292553; called by muse, mutect2, varscan2
- MYO1A | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs139153558; called by muse, mutect2, varscan2
- NEBL | c.54A>G p.I18M | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.066); catalogued as COSV65799805; called by muse, mutect2, varscan2
- NRXN1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs906827517, COSV101279430, COSV68018753; called by muse, mutect2
- OR1L6 | c.697C>A p.Q233K (on ENST00000373684; = p.Q197K on NM_001004453.2) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV59028744; called by muse, mutect2, varscan2
- PAX3 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs142651003, COSV60589590; called by muse, mutect2
- PCDHA4 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793107; called by muse, mutect2
- PGM5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV101123812; called by muse, mutect2
- PIK3CB | c.911T>G p.I304R | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.065); catalogued as COSV56687238; called by muse, mutect2, varscan2
- PLAAT3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV100071650; called by muse, mutect2
- PLEKHH2 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99174278; called by muse, mutect2
- PLOD3 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs776439156, COSV56183716; called by mutect2, varscan2
- PRDM10 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1304806508, COSV62604480; called by muse, mutect2, varscan2
- RASGRF1 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67249701; called by muse, mutect2, varscan2
- RBBP5 | c.761G>A p.W254* | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | catalogued as COSV52705313, COSV99196865; called by muse, mutect2, varscan2
- RNF113A | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65097529; called by muse, mutect2, varscan2
- RNF135 | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60433818; called by muse, mutect2, varscan2
- RNGTT | c.1507-2A>G p.X503_splice | Splice Site (SNP) | VAF 31/430 reads (7%) | catalogued as COSV99665387; called by muse, mutect2
- ROBO2 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs764613049, COSV59917574; called by muse, mutect2, varscan2
- RUNX1T1 | c.211T>C p.F71L (on ENST00000265814 / NM_001198628.1; = p.F44L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV56151347; called by muse, mutect2, varscan2
- SCAF8 | c.3698A>T p.D1233V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV65792474; called by muse, mutect2, varscan2
- SIGLEC8 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs370112420, COSV58474653; called by muse, mutect2, varscan2
- SLC12A3 | c.2859C>T p.S953= (on ENST00000563236 / NM_001126108.2; = p.S962= on NM_000339.3) | Splice Region (SNP) | VAF 7/61 reads (11%) | catalogued as rs749254306, COSV99343752; called by muse, mutect2, varscan2
- SLC35B4 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65984916; called by muse, mutect2, varscan2
- SRRM2 | c.3284A>T p.K1095M | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100070037; called by muse, mutect2
- SVOP | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54466519; called by muse, mutect2, varscan2
- TEKT5 | c.614T>C p.L205S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99295778; called by muse, mutect2, varscan2
- TEX2 | c.3261+2T>G p.X1087_splice (on ENST00000583097 / NM_001288733.2; = p.X1094_splice on NM_018469.5) | Splice Site (SNP) | VAF 16/204 reads (8%) | catalogued as COSV99366701; called by muse, mutect2
- TNR | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772521138, COSV54893337; called by muse, mutect2, varscan2
- TP53BP2 | c.3363+1G>A p.X1121_splice (on ENST00000343537 / NM_001031685.3; = p.X992_splice on NM_005426.2) | Splice Site (SNP) | VAF 4/53 reads (8%) | catalogued as COSV59070685; called by muse, mutect2
- TSR1 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV56785493; called by muse, mutect2, varscan2
- TTC7A | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs145006355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNL1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99469372; called by muse, mutect2
- XK | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.62); catalogued as rs782584346, COSV66119717; called by muse, mutect2
- RARG | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2
- WWOX | c.863G>T p.W288L | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.112); called by muse, mutect2
- ANKRD26 | c.2427T>C p.Y809= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV65776280; called by muse, mutect2, varscan2
- BCL9 | c.1599A>G p.P533= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2
- C10orf90 | c.789A>G p.S263= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as COSV99502908; called by muse, mutect2
- DMD | c.1404A>G p.E468= | Silent (SNP) | VAF 29/541 reads (5%) | catalogued as rs759585879, COSV99918900; called by muse, mutect2
- DNAH1 | c.6402G>A p.K2134= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV70230820; called by muse, mutect2, varscan2
- FCGR2B | c.498C>T p.F166= | Silent (SNP) | VAF 26/602 reads (4%) | catalogued as COSV99374811; called by muse, mutect2
- GBE1 | c.234C>T p.V78= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV70100275; called by muse, mutect2, varscan2
- GPAM | c.1632C>T p.V544= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV100788079; called by muse, mutect2
- HHIPL2 | c.807G>A p.G269= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs1370467295, COSV58568174; called by muse, mutect2, varscan2
- MRPS11 | c.465G>A p.G155= | Silent (SNP) | VAF 18/227 reads (8%) | catalogued as COSV100363678; called by muse, mutect2
- NDST4 | c.309A>C p.R103= | Silent (SNP) | VAF 27/262 reads (10%) | catalogued as COSV52124325; called by muse, mutect2, varscan2
- OR52K1 | c.408G>A p.T136= | Silent (SNP) | VAF 54/386 reads (14%) | catalogued as rs185726722; called by muse, mutect2, varscan2
- OTUD4 | c.765C>G p.V255= (on ENST00000447906 / NM_001366057.1; = p.V190= on NM_001102653.1) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV56850854; called by muse, mutect2, varscan2
- SSTR4 | c.813C>T p.C271= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV54798707; called by muse, mutect2, varscan2
- TBK1 | c.1080C>G p.V360= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV59156229; called by muse, mutect2, varscan2
- TC2N | c.1470T>A p.S490= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as COSV61747286; called by muse, mutect2, varscan2
- TFF2 | c.195G>A p.G65= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as rs1271861554; called by muse, mutect2
- TNRC6C | c.4128A>G p.K1376= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV100049369, COSV56946305; called by muse, mutect2
- TTC23 | c.1083C>G p.L361= | Silent (SNP) | VAF 12/376 reads (3%) | catalogued as rs1340653254, COSV100018338; called by muse, mutect2
- ZNF629 | c.1812C>T p.I604= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs780944187, COSV99354494; called by muse, mutect2
- ZNF76 | c.1107C>T p.G369= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs144970619; called by mutect2, varscan2
- ZSCAN31 | c.690G>A p.Q230= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100716852; called by muse, mutect2
- CLCA3P | n.39G>C | RNA (SNP) | VAF 5/129 reads (4%) | called by muse, mutect2
